Gene-level copy-number profile of tumor specimen TCGA-VS-A8EI-01A from TCGA case TCGA-VS-A8EI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 38.7 years (14,129 days).
Specimen TCGA-VS-A8EI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.eededb2a-6f5f-4b5d-b6ba-425871c7ac13.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A8EI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cf236058-3bef-404d-be64-be555bc16653

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 18,502; copy number 2: 32,684; copy number 3: 5,236; copy number 4: 2,808; copy number 5: 301; copy number 6: 132; copy number 7: 48; copy number 14: 40; copy number 19: 12; copy number 23: 27.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A8EI-01A-11D-A37M-01): tumor purity 0.43, ploidy 1.72, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:186,026,456–186,900,838, 21 genes: RNU4-64P, TLR3, FAM149A, AC104070.1, RPSAP70, ORAOV1P1, FLJ38576, CYP4V2, KLKB1, F11, F11-AS1, AC109517.1, SLC25A5P6, AC018709.1, RNU6-1055P, MTNR1A, FAT1, AC107050.1, AC108865.1, AC108865.2, MRPS36P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 560 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:200,695,723–204,067,363, 121 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr3:159,711,852–161,821,908, 39 genes, copy number 5: AC092943.2, AC092943.1, IQCJ-SCHIP1-AS1, RNU2-31P, SCHIP1, IL12A-AS1, IL12A, LINC01100, BRD7P2, C3orf80, AC079594.1, IFT80, RPL35AP10, SMC4, MIR15B, MIR16-2, TRIM59, B3GAT3P1, RNU7-136P, KPNA4, SCARNA7, KRT8P12, RPL6P8, ARL14, SNORA72, AC069224.1, PPM1L, B3GALNT1, NMD3, AC108738.1, EEF1GP4, PSMC1P7, SPTSSB, LINC02067, AC112491.1, RPL23AP42, OTOL1, AC112770.1, AC131211.1.
- chr3:189,238,686–190,122,437, 6 genes, copy number 5 (within-gene range 4–5): TPRG1-AS2, TP63, AC078809.1, MIR944, P3H2, MTAPP2.
- chr5:51,886,688–52,990,278, 13 genes, copy number 5: RNA5SP182, KATNBL1P4, AC091903.1, LINC02118, RPS17P11, MFSD4BP1, AC022126.1, PELO, ITGA1, AC022133.2, B3GNTL1P1, AC022133.1, AC025180.1.
- chr5:165,905,126–165,905,608, 1 gene, copy number 5: AC008489.1.
- chr12:23,529,504–30,879,268, 128 genes, copy number 6–23 (broad region; genes not listed).
- chr15:27,754,875–28,099,315, 1 gene, copy number 6 (within-gene range 2–6): OCA2.
- chr15:27,895,704–29,570,723, 46 genes, copy number 6 (within-gene range 4–6): RPL5P32, HERC2, RPL41P2, HERC2P1, AC091304.4, AC091304.1, AC091304.3, GOLGA8F, RN7SL238P, ABCB10P3, AC091304.8, AC091304.5, MIR4509-2, AC091304.10, AC091304.2, AC138749.4, MIR4509-3, AC138749.7, ABCB10P4, GOLGA8G, Metazoa_SRP, AC138749.3, AC138749.1, AC138749.2, HERC2P11, HERC2P9, AC055876.2, GOLGA8M, RN7SL719P, AC055876.5, WHAMMP2, AC055876.4, AC055876.1, AC055876.3, PDCD6IPP2, AC055876.6, GOLGA6L7, AC174071.1, AC174469.1, APBA2, AC127522.1, FAM189A1, AC061965.2, AC061965.1, NSMCE3, AC107980.1.
- chr15:90,717,346–96,551,517, 121 genes, copy number 5 (broad region; genes not listed).
- chr19:1,985,438–2,034,881, 1 gene, copy number 6 (within-gene range 2–6): BTBD2.
- chr19:2,002,580–2,944,971, 56 genes, copy number 6 (within-gene range 3–6): AC004678.2, AC004678.1, AC007136.1, MKNK2, MOB3A, IZUMO4, AP3D1, DOT1L, AC004490.1, PLEKHJ1, MIR1227, MIR6789, SF3A2, AMH, MIR4321, JSRP1, OAZ1, AC005258.1, PEAK3, LINGO3, AC104530.1, AC005258.2, LSM7, SPPL2B, TMPRSS9, TIMM13, LMNB2, MIR7108, LINC01775, GADD45B, RNU6-993P, GNG7, ELOCP28, RN7SL121P, AC092068.2, MIR7850, AC092068.1, AC092068.3, AC006538.3, DIRAS1, AC006538.2, AC006538.4, AC006538.1, SLC39A3, SGTA, THOP1, ZNF554, ZNF555, AC006130.1, AC006130.3, ZNF556, AC006130.2, AC119403.2, ZNF57, AC119403.1, ZNF77.
- chr21:36,632,681–38,121,345, 27 genes, copy number 7 (within-gene range 3–7): AP000696.1, AP000697.1, SIM2, HLCS, HLCS-IT1, RNA5SP491, DPRXP5, AP000704.1, Y_RNA, MRPL20P1, RIPPLY3, RNU6-696P, PIGP, TTC3, AP001429.1, TTC3-AS1, DSCR9, RN7SL678P, AP001432.1, VPS26C, AP001412.1, AP001437.2, AP001437.1, DYRK1A, AP001407.1, KCNJ6, KCNJ6-AS1.

Autosomal genes at a single copy (total copy number 1): 18,049. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
